MMRF case MMRF_1694 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b0c9eb44-47ca-43a8-b1e6-5baeb2682369

Demographics
Sex at birth: male; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.9 years (24,422 days); ISS stage: II; Days to last known disease status: 1,124 days (3.1 years); Days to last follow up: 1,124 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 108 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 168 days; Days to treatment end: 168 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 170 days; Days to treatment end: 170 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 394 days (1.1 years); Days to treatment end: 935 days (2.6 years).
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 931 days (2.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -24 (ECOG 0): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 3.52 g/L; Immunoglobulin A 53.7 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.48 µg/mL; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.09 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 9.5 g/dL; Glucose 4.29 mmol/L; C-Reactive Protein 0.194 mg/dL.
- Day 70: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.7 mg/dL; Immunoglobulin G 4.44 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.89 µg/mL; Hemoglobin 6.14 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 6.06 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 31 g/L; Total Protein 5.6 g/dL; Glucose 7.87 mmol/L.
- Day 144 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 7.04 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 2.23 µg/mL; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.74 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 4.13 mmol/L.
- Day 193 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 7.52 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.56 µg/mL; Lactate Dehydrogenase 4.45 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 5.83 mmol/L.
- Day 270 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Beta 2 Microglobulin 1.82 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.54 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 47 g/L; Total Protein 7.1 g/dL; Glucose 3.58 mmol/L.
- Day 375 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 8.3 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.77 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 5.45 mmol/L.
- Day 505: Serum Free Immunoglobulin Light Chain, Kappa 23.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.1 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2.21 µg/mL; Hemoglobin 7.44 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.63 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 4.68 mmol/L.
- Day 564 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.63 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.34 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 5.89 mmol/L.
- Day 637: Hemoglobin 7.32 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L.
- Day 784: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 38.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.4 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 4.48 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.59 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 47 g/L; Total Protein 8.2 g/dL; Glucose 4.07 mmol/L.
- Day 854: Hemoglobin 6.14 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.43 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L.
- Day 935: M Protein 0.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 12.4 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.65 µg/mL; Lactate Dehydrogenase 5.57 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.03 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 8.1 g/dL; Glucose 5.17 mmol/L.
- Day 1,026 (ECOG 0): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 5.37 g/L; Immunoglobulin A 6.41 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 1.84 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 5.83 mmol/L.
- Day 1,124 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 5.82 g/L; Immunoglobulin A 5.99 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.57 µg/mL; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.68 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 4.68 mmol/L.

Other clinical attributes
- Day -24: Weight: 106 kg; Height: 185 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1694_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -24 days.
- Sample MMRF_1694_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -24 days.
- Sample MMRF_1694_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 935 days (2.6 years).
